Somatic mutation profile of tumor specimen MMRF_1860_1_BM_CD138pos (aliquot MMRF_1860_1_BM_CD138pos_T1_KBS5U_L05553) from MMRF case MMRF_1860, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.1 years (16,843 days).
Specimen MMRF_1860_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b868631-d12b-4562-9a64-f3f65d225180.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1860_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1860_1_PB_Whole_C3_KBS5U_L05576; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9e0b344-0609-4b8f-9d63-74b03d87266f

The open-access MAF lists 39 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Intron 7, 3'UTR 4, 3'Flank 2, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 71/197 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- AGXT2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51484777; called by muse, mutect2, varscan2
- DPAGT1 | c.497-5C>T | Splice Region (SNP) | VAF 20/52 reads (38%) | catalogued as rs556782038; called by muse, mutect2, varscan2
- ERN2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as COSV56833563; called by muse, mutect2
- FBLN1 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753148981; called by muse, mutect2, varscan2
- IGKV1-5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/23 reads (74%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as rs772574976; called by muse, mutect2, varscan2
- LRP2 | c.7625G>A p.R2542H | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778298000, COSV55576946; called by muse, mutect2, varscan2
- OR5J2 | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs149835720; called by muse, mutect2, varscan2
- OR5M3 | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs1424697215, COSV100392594; called by muse, mutect2, varscan2
- TENT4A | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50101974; called by muse, mutect2
- XDH | c.2461G>A p.G821S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); catalogued as rs765777817, COSV65147788; called by muse, mutect2, varscan2
- ZFHX3 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs771899311; called by muse, mutect2, varscan2
- ATP1A4 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CXCL12 | c.62-2A>C p.X21_splice | Splice Site (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- ERAP2 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 115/299 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHJ2 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 34/40 reads (85%) | PolyPhen probably damaging (0.995); called by muse, varscan2
- WTAP | c.441dup p.T148Yfs*3 | Frame Shift Ins (INS) | VAF 42/289 reads (15%) | called by mutect2, varscan2
- DDIT4 | c.378G>A p.Q126= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV56577245; called by muse, mutect2, varscan2
- HMCN1 | c.4113G>T p.S1371= | Silent (SNP) | VAF 87/226 reads (38%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.84G>A p.Q28= | Silent (SNP) | VAF 50/65 reads (77%) | catalogued as rs747279155; called by muse, varscan2
- LRFN5 | c.108T>A p.L36= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- PKD2L1 | c.1809G>A p.S603= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as rs767870703; called by muse, mutect2, varscan2
- PTPN13 | c.480C>T p.S160= | Silent (SNP) | VAF 69/162 reads (43%) | called by muse, mutect2, varscan2
- RAI14 | c.2942A>G p.*981= | Silent (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- U2SURP | c.27T>G p.S9= | Silent (SNP) | VAF 57/128 reads (45%) | catalogued as COSV67533002; called by muse, mutect2, varscan2
- CAMKV | c.*157C>A | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- CSTF2T | c.*1400G>T | 3'UTR (SNP) | VAF 35/101 reads (35%) | called by muse, mutect2, varscan2
- CYFIP2 | c.666+43del | Intron (DEL) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- DCD | c.98-422del | Intron (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- DNMT1 | c.995+55T>A | Intron (SNP) | VAF 100/290 reads (34%) | called by muse, mutect2
- MPZL2 | c.*12+280A>G | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- OR2G6 | chr1:248522665 del T | 3'Flank (DEL) | VAF 148/422 reads (35%) | called by mutect2, pindel, varscan2
- SERBP1 | chr1:67407967 del TTAAA | 3'Flank (DEL) | VAF 37/102 reads (36%) | catalogued as rs767218842; called by mutect2, pindel, varscan2
- SLC2A5 | c.571+761G>C | Intron (SNP) | VAF 80/188 reads (43%) | called by muse, mutect2, varscan2
- SPOCK2 | c.*852_*853del | 3'UTR (DEL) | VAF 56/166 reads (34%) | called by mutect2, pindel*, varscan2
- TCOF1 | c.1894-51G>A | Intron (SNP) | VAF 30/68 reads (44%) | catalogued as rs774564245; called by muse, mutect2
- TCOF1 | c.1894-49G>A | Intron (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2
- TGFBR1 | c.*1963T>G | 3'UTR (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- ZNF285B | n.135G>A | RNA (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
